Gene-level copy-number profile of tumor specimen TCGA-P5-A780-01A from TCGA case TCGA-P5-A780, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 44.2 years (16,161 days).
Specimen TCGA-P5-A780-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.2a77d937-8a1a-4174-b04a-61d74eabcafe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P5-A780-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b58ca3ab-d229-40f3-b943-a663da6f1c59

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 53; copy number 2: 2,845; copy number 3: 12,251; copy number 4: 42,227; copy number 5: 548; copy number 6: 581; copy number 7: 774; copy number 8: 270; copy number 9: 131; copy number 10: 132.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P5-A780-01A-12D-A32A-01): tumor purity 0.57, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 263 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:1,177,313–1,737,525, 1 gene, copy number 9 (within-gene range 8–9): ADARB2.
- chr10:1,290,018–16,513,745, 262 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
